Somatic mutation profile of tumor specimen 0DVPNL from CCDI case PBCMYJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 8.4 years (3,051 days).
Specimen 0DVPNL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaa42c17-7467-4cd4-aa82-51c4aba1cbb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d164a28f-1658-4336-a20c-c2955a159c21

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 349/772 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 308/1140 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 445/511 reads (87%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AFAP1L1 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 253/742 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs755708543; called by muse, mutect2, varscan2
- C2 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 201/898 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs779079998; called by muse, mutect2, varscan2
- HMCN1 | c.10981C>T p.R3661W | Missense Mutation (SNP) | VAF 157/1391 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.863); catalogued as rs770186866; called by muse, mutect2, varscan2
- SHROOM2 | c.4734C>A p.F1578L | Missense Mutation (SNP) | VAF 110/608 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV66605933; called by muse, mutect2, varscan2
- FZD10 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 100/746 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR101 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 186/524 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PDS5A | c.3977C>T p.A1326V | Missense Mutation (SNP) | VAF 473/1130 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POLA1 | c.4036T>A p.L1346M | Missense Mutation (SNP) | VAF 114/704 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); called by muse, varscan2
- HMCN2 | c.6186C>T p.S2062= | Silent (SNP) | VAF 657/1624 reads (40%) | catalogued as rs982085889; called by muse, mutect2, varscan2
- PIK3CD | c.396C>T p.C132= | Silent (SNP) | VAF 208/752 reads (28%) | catalogued as rs189908126, COSV63127550; called by muse, mutect2, varscan2
- VWCE | c.2187C>T p.A729= | Silent (SNP) | VAF 24/470 reads (5%) | catalogued as rs1031351168; called by muse, mutect2
- CCL19 | c.*31C>T | 3'UTR (SNP) | VAF 204/933 reads (22%) | catalogued as rs370509358; called by muse, mutect2, varscan2
